Gene-level copy-number profile of tumor specimen TCGA-4Z-AA7R-01A from TCGA case TCGA-4Z-AA7R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.3 years (26,781 days).
Specimen TCGA-4Z-AA7R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3849d463-21e9-41cc-8060-8ee067246010.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA7R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27fc1d36-1d25-48e8-b542-f6a70317bf50

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,503; copy number 2: 14,844; copy number 3: 27,386; copy number 4: 8,531; copy number 5: 3,854; copy number 6: 1,742; copy number 7: 1,285; copy number 8: 428; copy number 9: 20; copy number 10: 108; copy number 12: 15; copy number 39: 14; copy number 43: 17; copy number 44: 4; copy number 52: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA7R-01A-11D-A390-01): tumor purity 0.93, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,934 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,899,979–162,787,405, 127 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:171,485,551–174,995,308, 64 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr1:183,613,537–185,157,072, 27 genes, copy number 9–12: AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L.
- chr1:185,171,335–185,171,710, 1 gene, copy number 12: RPL22P24.
- chr2:175,022,214–194,188,309, 272 genes, copy number 7–9 (broad region; genes not listed).
- chr4:53,899,871–55,161,880, 26 genes, copy number 8: AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2.
- chr6:9,596,110–10,222,161, 4 genes, copy number 44: OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P.
- chr6:19,143,695–24,426,194, 57 genes, copy number 39–52: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2.
- chr6:43,076,307–46,606,162, 83 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:106,570,771–107,661,306, 17 genes, copy number 43 (within-gene range 3–43): RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1.
- chr7:12,685,637–18,027,846, 58 genes, copy number 7: AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1.
- chr7:18,127,220–18,127,309, 1 gene, copy number 7: MIR1302-6.
- chr7:51,716,657–53,947,804, 21 genes, copy number 7: RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854.
- chr7:106,624,072–118,496,171, 156 genes, copy number 7 (broad region; genes not listed).
- chr8:38,269,704–38,382,272, 1 gene, copy number 7 (within-gene range 5–7): NSD3.
- chr8:38,335,981–40,172,612, 41 genes, copy number 7: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:74,891,151–85,646,325, 141 genes, copy number 7 (broad region; genes not listed).
- chr8:116,642,130–117,176,714, 11 genes, copy number 7: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P.
- chr8:131,129,761–131,432,869, 3 genes, copy number 7: AC087341.1, AC104257.1, SNORA72.
- chr9:10,532,145–10,830,308, 5 genes, copy number 7: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1.
- chr9:27,948,078–30,935,977, 19 genes, copy number 7 (within-gene range 5–7): LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4.
- chr10:8,161,260–33,917,804, 426 genes, copy number 7 (broad region; genes not listed).
- chr10:35,079,598–38,783,108, 78 genes, copy number 7 (broad region; genes not listed).
- chr14:40,954,693–41,904,549, 8 genes, copy number 10 (within-gene range 5–10): LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1.
- chr15:19,878,555–23,856,375, 176 genes, copy number 8 (broad region; genes not listed).
- chr15:84,526,781–87,029,052, 57 genes, copy number 7 (within-gene range 4–7): UBE2Q2P1, LINC00933, AC048382.5, ZSCAN2, AC048382.1, AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, AC012291.3, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1, LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1.
- chr15:101,116,603–101,933,350, 31 genes, copy number 7: AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:54,477,796–56,511,659, 23 genes, copy number 8 (within-gene range 5–8): ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1.

Autosomal genes at a single copy (total copy number 1): 1,435. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
